Surgical pathology report (de-identified scan), TCGA case TCGA-CC-A9FW, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-A9FW-01A (Primary Tumor).

[page 1 of 4]
Clinical Case Report (For Collection of Cancerous Tissue)

ICD O-3

Carcinoma, Hepatocellular
NOS 817013
Site: Liver C22.0
Q1 4/7/19

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status		Race
		☐ Single ☒ Married ☐ Divorced ☐ Widow		VIETNAMESE Blood Pressure
Gender	Weight			Heart Rate
☒ Male ☐ Female				

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	Fever; yellow skin; tired of eating; fatigue
Symptoms:	Weight loss
Clinical Findings:	
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 4]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses		# of Pregnancies
	Date of Last Menses		# of Live Births
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____			☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		1 pack/day	(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		1 drink/day	(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 4]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	A tumour was found in the liver	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging	Date of Diagnosis	
T3 N0 M0 Stage: IIA		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of the right liver			
Primary Tumor			
Organ	Detailed Location	Size	
Liver tumour	Right liver	8 x 7 x 6 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T3 N0 M0 Stage: IIA			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 4]
Consolidated Pathology Diagnosis

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse					Streaming						
Mosaic			✓		Storiform						
Necrosis				✓	Fibrosis						
Lymphocytic Infiltration			✓		Palisading						
Vascular Invasion				✓	Cystic Degeneration						
Clusterized			✓		Bleeding						
Alveolar Formation				✓	Myxoid Change						
Indian File				✓	Psammoma/Calcification						

Cellular Differentiation																			
Squamous			+	-	Adenomatous			+	-	Sarcomatous			+	-	Lymphomatous			+	-
Squamoid Cell					Glandular cell			✓		Round Cell					Large Cell				
Spindle Cell					Cell Stratification			✓		Fibroblast					Small Cell				
Keratin					Secretion			✓		Osteoblast					RS Cell/RS Like				
Desmosome					Intracyt. Vacuole			✓		Lipoblast					Inflam. Cell				
Pearl					Gland formation			✓		Myoblast					Plasma Cell				

Cellular Differentiation:				☐ Well	☒ Moderate	☐ Poor
---------------------------	--	--	--	-------------------------------	--	-------------------------------

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis			✓	
Hyperchromatism			✓	
Nucleolar Prominent			✓	
Multinucleated Giant Cell			✓	
Mitotic Activity			✓	
Nuclear Grade:				

Final Pathology Report

Histological Diagnosis: Hepato cellular Carcinoma **Grade:** 2

Comments:

Director, Research Pathology

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS - F

Case is (check):		

Source: NCI Genomic Data Commons file d612e2a0-724d-4eb2-b70f-5abb9881e79a (TCGA-CC-A9FW.81241A65-A7E2-4783-944C-58BB6BDA3F5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).